Somatic mutation profile of tumor specimen TCGA-AC-A3OD-01A (aliquot TCGA-AC-A3OD-01A-11D-A21Q-09) from TCGA case TCGA-AC-A3OD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.0 years (25,186 days).
Specimen TCGA-AC-A3OD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11988028-c6c2-44d0-b9b3-c7233ec5567a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A3OD-10A (Blood Derived Normal), aliquot TCGA-AC-A3OD-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7100f00a-be40-4ef7-9942-f994de63110b

The open-access MAF lists 27 somatic variants for this specimen: 24 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 18, Nonsense Mutation 5, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1921C>T p.Q641* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as rs587782750, COSV55729418; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 31/84 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP7 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as rs560738276, COSV58700317; called by muse, mutect2, varscan2
- ADSL | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as CM044204, COSV99342226; called by muse, mutect2
- CCDC7 | c.3163C>T p.R1055* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs140481991; called by mutect2, varscan2
- FATE1 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs758256359, COSV64849270; called by muse, mutect2, varscan2
- HYDIN | c.13148G>A p.R4383Q | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368513191; called by muse, mutect2, varscan2
- IRAG1 | c.1875G>T p.Q625H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV70212745; called by muse, mutect2, varscan2
- KCNF1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.154); catalogued as COSV54465292; called by muse, mutect2, varscan2
- MAGEB16 | c.927T>G p.Y309* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV67874450; called by muse, mutect2
- OPN4 | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV53948158; called by muse, mutect2, varscan2
- PCDH11X | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs1161362870, COSV100011655; called by muse, mutect2, varscan2
- POLR3D | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60572069; called by muse, mutect2, varscan2
- PPP6R3 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV55734711; called by mutect2, varscan2
- RHOC | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV53519088; called by muse, mutect2, varscan2
- RNF40 | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.373); catalogued as rs751674221, COSV61216402; called by muse, mutect2, varscan2
- SF1 | c.1407G>A p.M469I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV99918306; called by muse, mutect2
- SLC8A2 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1158838372, COSV52642381; called by muse, mutect2, varscan2
- TIAM2 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.105); catalogued as rs756072856, COSV100020149, COSV59701810; called by muse, mutect2, varscan2
- TIMP1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV54483811; called by muse, mutect2, varscan2
- WDFY3 | c.4103T>C p.L1368S | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV99883490; called by muse, mutect2
- ZSWIM2 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54578824; called by muse, mutect2, varscan2
- CHUK | c.2167_2168del p.I723Yfs*3 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | called by mutect2, pindel, varscan2
- CLASP1 | c.4608G>A p.T1536= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs376528877; called by muse, mutect2, varscan2
- IRF4 | c.942C>T p.G314= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs373069653; called by muse, mutect2, varscan2
- SRPRA | c.1414T>C p.L472= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs761323833, COSV55008615; called by muse, mutect2, varscan2
